Somatic mutation profile of tumor specimen ALCH-B20D-TTP1-A (aliquot ALCH-B20D-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B20D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.9 years (25,889 days).
Specimen ALCH-B20D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b344306-fa53-450c-9112-c111c1ac0324.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B20D-NB1-A (Blood Derived Normal), aliquot ALCH-B20D-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ea2e04a-0d42-4d68-9656-39171f58dc07

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG1 | c.2278G>T p.D760Y | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DST | c.21896C>T p.S7299F (on ENST00000361203 / NM_001374722.1; = p.S4972F on NM_015548.5) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM74 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2
- WDR72 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- GNAO1 | c.339G>A p.R113= | Silent (SNP) | VAF 10/169 reads (6%) | catalogued as COSV99341306; called by muse, mutect2
- PYCR1 | c.255C>T p.D85= | Silent (SNP) | VAF 14/410 reads (3%) | called by muse, mutect2
- DBNDD1 | chr16:90019803 G>A | 5'Flank (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- IRX3 | c.*16A>T | 3'UTR (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
